Gene-level copy-number profile of tumor specimen TCGA-AA-A01C-01A from TCGA case TCGA-AA-A01C, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Ascending colon; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 75.9 years (27,729 days).
Specimen TCGA-AA-A01C-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-COAD.5d9debf1-fb66-42a0-848b-74b1d8d20770.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AA-A01C-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 392 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/e7298b69-9559-4f73-9fd2-d676042acb56

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 2: 3,834; copy number 3: 14,584; copy number 4: 31,424; copy number 5: 7,409; copy number 6: 1,273; copy number 7: 249; copy number 8: 1,105; copy number 9: 353.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-AA-A01C-01A-01D-A008-01): tumor purity 0.6, ploidy 3.01, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 353 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr20:4,120,980–23,879,748, 341 genes, copy number 9 (broad region; genes not listed).
- chr20:52,192,159–52,890,386, 9 genes, copy number 9 (within-gene range 8–9): LINC01524, AL109610.1, AL049765.2, AL049765.1, MRPS33P4, AL031674.1, AL161945.1, AL121902.1, RPL36P1.
- chr20:53,097,652–53,179,550, 3 genes, copy number 9: RN7SKP184, AL391097.3, AL391097.1.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
